Somatic mutation profile of tumor specimen TCGA-EL-A3CW-01A (aliquot TCGA-EL-A3CW-01A-11D-A19J-08) from TCGA case TCGA-EL-A3CW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-EL-A3CW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5ea2a1f-95a3-4ab4-aa99-70caf3a78a0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CW-10A (Blood Derived Normal), aliquot TCGA-EL-A3CW-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d797f3b-6acb-4ccc-bb77-325d76e2cddb

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3M1 | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53008441; called by muse, mutect2
- YWHAG | c.418G>T p.G140* | Nonsense Mutation (SNP) | VAF 7/155 reads (5%) | catalogued as COSV56900733; called by muse, mutect2
- CDPF1 | c.222C>T p.G74= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV53078054; called by muse, mutect2
- FMN2 | c.3099G>T p.P1033= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs201587786, COSV60419577; called by muse, varscan2
